Somatic mutation profile of tumor specimen TCGA-JW-A5VH-01A (aliquot TCGA-JW-A5VH-01A-11D-A28B-09) from TCGA case TCGA-JW-A5VH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 53.2 years (19,423 days).
Specimen TCGA-JW-A5VH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b7bffe4-f113-4e06-b36d-e82c15d4dc88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JW-A5VH-10A (Blood Derived Normal), aliquot TCGA-JW-A5VH-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f33f0146-fa54-4eca-9cb2-24fff90957b6

The open-access MAF lists 74 somatic variants for this specimen: 60 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 13, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, Intron 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 53/114 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 26/56 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.253+1G>T p.X85_splice | Splice Site (SNP) | VAF 28/37 reads (76%) | hotspot (GDC flag); catalogued as rs587776667, CS110215, CS1314439, CS971885, COSV64288843, COSV64289910, COSV64295724; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- ADAM32 | c.1365T>G p.H455Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as COSV65949106; called by muse, mutect2
- APOBEC4 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.428); catalogued as COSV58017610, COSV58017694; called by muse, mutect2, varscan2
- ARHGEF2 | c.2389C>T p.P797S (on ENST00000361247 / NM_001162383.2; = p.P769S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.64); PolyPhen benign (0.117); catalogued as COSV58110855; called by muse, mutect2, varscan2
- ARID1A | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 47/59 reads (80%) | catalogued as COSV61376109; called by muse, mutect2, varscan2
- ATP8B3 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs775293943, COSV59542560; called by muse, mutect2, varscan2
- B3GALT4 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65851541; called by muse, mutect2, varscan2
- CCDC134 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1465097519, COSV55388001; called by muse, mutect2, varscan2
- CCDC78 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs896397771, COSV52402189; called by muse, mutect2, varscan2
- CD163 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781525056, COSV100775631, COSV63132115; called by muse, mutect2, varscan2
- CNOT1 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV57780544; called by muse, mutect2
- CNTNAP5 | c.1366A>C p.N456H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); catalogued as COSV70485096; called by muse, mutect2, varscan2
- COL7A1 | c.1007A>C p.Q336P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as CD1211187, COSV60394999; called by muse, mutect2, varscan2
- DCLK3 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749324049, COSV69363089; called by muse, mutect2, varscan2
- DNAAF3 | c.915G>A p.T305= (on ENST00000524407 / NM_001256715.2; = p.T352= on NM_178837.4) | Splice Region (SNP) | VAF 16/57 reads (28%) | catalogued as COSV61275639, COSV61276910; called by muse, mutect2, varscan2
- DNAH2 | c.8318G>A p.R2773H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374110523; called by muse, mutect2, varscan2
- EYA1 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV58162371; called by muse, mutect2, varscan2
- FOXRED2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143739893; called by muse, mutect2, varscan2
- GFPT1 | c.1100A>C p.Y367S (on ENST00000357308 / NM_001244710.2; = p.Y349S on NM_002056.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV61947968; called by muse, mutect2, varscan2
- GFPT2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs753499695, COSV53808391; called by muse, mutect2, varscan2
- GMCL1 | c.39A>T p.R13S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57001587; called by muse, mutect2
- GNPTAB | c.553T>C p.F185L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.363); catalogued as COSV54779722; called by muse, mutect2, varscan2
- GPR78 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV66763046; called by muse, mutect2
- GYS2 | c.1320G>T p.L440F | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV53923132; called by muse, mutect2, varscan2
- IMPG2 | c.1386C>A p.H462Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV51977976; called by muse, mutect2, varscan2
- ITIH2 | c.776G>T p.R259I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64432333, COSV64433257; called by muse, mutect2, varscan2
- KCNA6 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1339393552, COSV54975149; called by muse, mutect2, varscan2
- KRAS | c.62T>G p.I21R | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV104372657, COSV55705588; called by muse, mutect2, varscan2
- LIMK2 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs138454239; called by muse, mutect2, varscan2
- MEFV | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.723); catalogued as COSV54821651; called by muse, mutect2, varscan2
- NLGN4X | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760432673, COSV52002990; called by muse, mutect2, varscan2
- OTUD5 | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as COSV50235279; called by muse, mutect2, varscan2
- PCDH15 | c.5212G>T p.E1738* | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as COSV64692716, COSV64746606; called by muse, mutect2, varscan2
- PFKFB1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 40/108 reads (37%) | PolyPhen probably damaging (1); catalogued as rs747113593, COSV66627772; called by muse, mutect2, varscan2
- PKHD1 | c.8777G>A p.R2926Q | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs1270162093, COSV61874548; called by muse, mutect2, varscan2
- PLD1 | c.920T>C p.I307T | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs1373033088, COSV100578123, COSV60567874; called by muse, mutect2, varscan2
- PLXNB2 | c.3799G>A p.V1267M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs375409236; called by muse, mutect2, varscan2
- POLA1 | c.1513C>G p.Q505E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV66886046; called by muse, mutect2, varscan2
- PPFIA3 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61951564; called by muse, mutect2, varscan2
- PPIAL4G | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV70087034; called by muse, mutect2, varscan2
- PTPN4 | c.2584C>A p.L862I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV55301293; called by muse, mutect2, varscan2
- PTPRC | c.3458C>T p.S1153F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.086); catalogued as rs724159907, COSV61411324, COSV61414534; called by muse, mutect2, varscan2
- RASGRP2 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs202192382, COSV62449439; called by muse, mutect2, varscan2
- RERGL | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57461904; called by muse, mutect2, varscan2
- SEC16B | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs147207337, COSV100381287; called by muse, mutect2, varscan2
- SF3B3 | c.2411A>G p.H804R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV56787393; called by muse, mutect2, varscan2
- SGSM3 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1389157498, COSV50652157; called by muse, mutect2, varscan2
- SYNE1 | c.5490G>T p.L1830F (on ENST00000367255 / NM_182961.4; = p.L1837F on NM_033071.3) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV54976830; called by muse, mutect2, varscan2
- TAB3 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs950225626, COSV55836812; called by muse, mutect2, varscan2
- TNFAIP8L1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100542357; called by muse, mutect2, varscan2
- TRRAP | c.9188G>A p.R3063Q (on ENST00000359863 / NM_001244580.1; = p.R3034Q on NM_003496.3) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62844029; called by muse, mutect2, varscan2
- USH2A | c.11714G>A p.R3905H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201709470, COSV56366631; ClinVar: uncertain significance; called by muse, mutect2
- ZNF518A | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs782531264, COSV60151216; called by muse, mutect2, varscan2
- IGKV1-17 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PPIP5K2 | c.1224dup p.D409* | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- ZEB2 | c.1044del p.K349Rfs*21 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- ADCY8 | c.558C>T p.N186= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV53906716; called by muse, mutect2, varscan2
- ANGPTL1 | c.882T>C p.Y294= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs757986240, COSV52366328; called by muse, mutect2, varscan2
- CACNA1H | c.5877C>A p.G1959= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as rs1314631160, COSV52357558, COSV99326403; called by muse, mutect2, varscan2
- CCDC134 | c.543A>T p.P181= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV55388010; called by muse, mutect2, varscan2
- CDH10 | c.222C>T p.Y74= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs559158011, COSV100050696, COSV52576717; called by muse, mutect2, varscan2
- DMRTC2 | c.198C>T p.C66= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs369030903; called by muse, mutect2, varscan2
- ELP2 | c.174C>A p.T58= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV52369120; called by muse, mutect2, varscan2
- GTF2F1 | c.1458C>T p.S486= | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as rs1027436046, COSV55532210; called by muse, mutect2, varscan2
- LRP5 | c.4359C>T p.C1453= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs755205426, COSV53715427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTMR10 | c.1452C>A p.S484= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV58728173, COSV58728861; called by muse, mutect2, varscan2
- OR13A1 | c.546G>T p.L182= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV65572343; called by muse, mutect2, varscan2
- SCARA5 | c.1272G>A p.K424= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV61571993; called by muse, mutect2, varscan2
- TNNT1 | c.495G>T p.L165= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99402720; called by muse, mutect2, varscan2
- PFKP | c.1684-4640C>T | Intron (SNP) | VAF 36/87 reads (41%) | catalogued as rs539611230; called by muse, mutect2, varscan2
